TCGA case TCGA-77-8144 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86be9147-65f6-43f4-a3e9-5e5f422bd0ff

Demographics
Sex at birth: male; Country of residence at enrollment: Australia; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,796 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 833 days (2.3 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 833.

Other clinical attributes
- DLCO (% of predicted): 73; FEV1/FVC before bronchodilator (%): 50.4; FEV1 before bronchodilator (% of reference): 71.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 59; Tobacco smoking onset year: 1944.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-77-8144-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.5.
  Slide TCGA-77-8144-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-77-8144-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-77-8144-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1: Lost to follow-up: Yes; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 833 days; disease-specific survival: no event (censored), 833 days; disease-free interval: no event (censored), 833 days; progression-free interval: no event (censored), 833 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-77-8144-01A-11D-2243-01): tumor purity 0.57, ploidy 3.6, whole-genome doublings 1.
